Somatic mutation profile of tumor specimen TCGA-L6-A4ET-01A (aliquot TCGA-L6-A4ET-01A-11D-A257-08) from TCGA case TCGA-L6-A4ET, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVC; Age at diagnosis: 49.2 years (17,978 days).
Specimen TCGA-L6-A4ET-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f34717c8-048f-4d17-b08b-12c972c057b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L6-A4ET-10A (Blood Derived Normal), aliquot TCGA-L6-A4ET-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4637cad2-679e-4428-abbe-89c3ea82cf9a

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 5, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ANGPTL7 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771394500, COSV63880241; called by mutect2, varscan2
- PDSS1 | c.1207C>A p.L403I | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV61018506; called by muse, mutect2, varscan2
- UBE4A | c.373G>C p.D125H | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.172); catalogued as COSV52805427; called by muse, mutect2
- KLHL2 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2
- FLII | c.2730C>T p.F910= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV100375601; called by muse, mutect2
- KYNU | c.972T>G p.P324= | Silent (SNP) | VAF 57/163 reads (35%) | catalogued as COSV51587229; called by muse, mutect2, varscan2
- PAQR4 | c.90G>A p.R30= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs1281653053, COSV51891962; called by muse, mutect2
- SMCHD1 | c.2862A>G p.L954= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as COSV55262134; called by muse, mutect2, varscan2
